Gene-level copy-number profile of tumor specimen TCGA-FB-AAQ6-01A from TCGA case TCGA-FB-AAQ6, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 85.7 years (31,319 days).
Specimen TCGA-FB-AAQ6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.50729a69-431b-4d28-8099-824158aa7566.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FB-AAQ6-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a06ca0d-dc90-48e4-a75e-087797bbf786

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,502; copy number 2: 44,313; copy number 3: 2,991; copy number 11: 4; copy number 23: 8; copy number 24: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FB-AAQ6-01A-11D-A40V-01): tumor purity 0.65, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,253,213–127,742,951, 9 genes, copy number 23–24 (within-gene range 4–24): AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 23: MIR1204.
- chr8:142,111,414–142,209,003, 3 genes, copy number 11 (within-gene range 3–11): AC103758.1, MIR4472-1, LINC00051.
- chr8:142,247,585–142,247,866, 1 gene, copy number 11: RN7SL260P.

Autosomal genes at a single copy (total copy number 1): 10,081. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
